Surgical pathology report (de-identified scan), TCGA case TCGA-09-1661, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1661-01B (Primary Tumor).

[page 1 of 8]
TCGA-09-1661

Specimen(s) Received

Ovary +/- tube, neoplasticm, right, fs

Taken: [REDACTED] **Received:** [REDACTED]

H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1,
Frozen section,
first x 1

B: Omentum, resection for tumor, fs

Taken: [REDACTED]

H&E, First x 1, H&E, First x 1, H&E, First x 1, Frozen section, each additional x 1

C: Left ovary

Taken: [REDACTED]

H&E, First x 1

D: Right pelvic lymph node

Taken: [REDACTED]

H&E, First x 1, H&E, First x 1, H&E, First x 1

E: Right obturator lymph node

Taken: [REDACTED]

H&E, First x 1, H&E, First x 1

F: Left pelvic lymph node

Taken: [REDACTED]

H&E, First x 1, H&E, First x 1

G: Small bowel adhesions

Taken: [REDACTED]

H&E, First x 1

H: Small bowel mesentary

Taken: [REDACTED]

H&E, First x 1

I: Small bowel mesentary #2

Taken: [REDACTED]

H&E, First x 1

J: Sigmoid tumor

Taken: [REDACTED]

H&E, First x 1

K: Omentum #2

Taken: [REDACTED]

H&E, First x 1

L: Infra gastric omentum

Taken: [REDACTED]

H&E, First x 1

M: Small intestine, resection for tumor

Taken: [REDACTED]

H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1

N: Hepatic flexure tumor

Taken: [REDACTED]

H&E, First x 1

Page 1 of 8

O: Cecum

Taken: [REDACTED]

H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1

Final Pathologic Diagnosis:

A: Right ovary, Salpingo-oophorectomy: Papillary serous carcinoma, involving ovary and

fallopian tube, (FIGO grade III). See comment.

Omentum, excision: Fibroadipose tissue with metastatic papillary serous

[page 2 of 8]
carcinoma.

C: Left ovary, oophorectomy: Atrophy; no tumor seen.

D: Lymph nodes, right pelvic, dissection: 8 lymph nodes with no tumor seen (0/8).

(Lymph nodes, right obturator, dissection: 5 lymph nodes with no tumor seen (0/5).

F: Lymph nodes, left pelvic, dissection: 4 lymph nodes with no tumor seen (0/4).

G: Small bowel, adhesions, excision: Fibroadipose tissue with crush artifact.

H: Mesentery, small bowel, excision: Fibroadipose tissue with metastatic papillary

serous carcinoma.

I: Mesentery, "small bowel #2", excision: Fibroadipose tissue with metastatic papillary

serous carcinoma.

J: Sigmoid colon, excision: Fibroadipose tissue with metastatic papillary serous carcinoma.

K: Omentum, "#2", excision: Fibroadipose tissue with metastatic papillary serous

carcinoma.

L: Omentum, infragastric, excision: Fibroadipose tissue with metastatic papillary serous

carcinoma.

M: Small intestine, resection: Metastatic papillary serous carcinoma involving mesentery

(; and bowel serosa.

N: Soft tissue, hepatic flexure, excision: Fibroadipose tissue with metastatic papillary

serous carcinoma.

O: Cecum, resection: Metastatic papillary serous carcinoma involving pericolonc fat

with focal extension into muscularis propria.

Note:

Ovarian Tumor Synoptic Comment

1. Type of tumor: Papillary serous carcinoma.

2. Grade of tumor: Grade III.

3. Location of tumor: Right ovary.

Page 2 of 8

4. Diameter of tumor: 5.5 cm in greatest dimension.

5. Appearance of surface of ovary: Smooth.

6. Condition of capsule: Intact

7. Appearance of cut surface: Solid.

8. Color of solid areas: White.

9. Necrosis: Focal.

10. Lymphatic/vascular invasion: Not identified.

11. Sites of metastases in pelvis: Right fallopian tube.

12. Pelvic lymph nodes: 12 lymph nodes with no tumor seen.

(Sites of metastases in abdomen: Omentum, Small bowel serosa and cecum muscularis

[page 3 of 8]
propria.

14. Para-aortic lymph nodes: 5 lymph nodes with no tumor seen.

15. Peritoneal cytology: Positive Cytology accession number: [REDACTED]

16. Other significant findings: None.

17. FIGO stage: III

.. TNM stage: pT3bN0Mx

[REDACTED] has reviewed the case and agrees with the diagnosis.

Intraoperative Consult Diagnosis

FS1 (A) Right ovary, excision: Poorly differentiated carcinoma. [REDACTED]

FS2 (B) Omentum, excision: Poorly differentiated carcinoma. ([REDACTED])

Clinical History

The patient is a [REDACTED] status post TAH in [REDACTED] and now presents with a 6.0 cm complex

mass of the pelvis. CA 125 = 146.

Gross Description

The specimen is received in fifteen parts, each labeled with the patient's name and medical record number.

Part A, received fresh and labeled "right ovary + tube," consists of one ovary measuring 6.1 x 3.2 x 3.0 cm.

Also included with the specimen is one fallopian tube measuring 5.5 x 2.2 x 1.0 cm. The ovary is large and

misshapen, and weighs 42 gm. On cut section, the ovarian parenchyma is completely replaced by a white,

semi-soft, solid parenchyma. The second portion of the specimen is a fallopian tube which appears to be

adhesed to fat and several nodules. The nodules have the same color and consistency of the ovarian

parenchyma, previously described. On cut section, the majority of the fallopian tube appears to be replaced

by the white parenchyma. A representative portion of white tumor is submitted for frozen section and the

unused frozen section is submitted in cassette A1. Representative pieces of tissue are submitted for tissue

banking and to Oncotech. The specimen is submitted as follows:

Cassette A1: Frozen section of ovary.

Cassettes A2-A5: Representative sections of ovary.

Cassette A6: Representative section of fallopian tube and associated cyst.

Cassette A7: Representative section of fallopian tube.

Part B, received fresh and labeled "omentum," consists of one piece of fibrofatty tissue measuring 18.2 x 6.4

x 0.6 cm. Within the specimen, there are multiple white, firm nodules, the largest measuring 3.4 cm in

greatest dimension. Representative sections are submitted for frozen section, with the unused portion of

frozen section submitted in cassette B1. Representative section of the nodules is also submitted in

cassettes [REDACTED]

Part C, labeled "left ovary," consists of one ovary measuring 3.6 x 2.1 x 0.8 cm. On cut section, the

parenchyma appears unremarkable. Representative sections are submitted in cassette [REDACTED]

Part D, labeled "right pelvic lymph node," consists of multiple pieces of fibrofatty tissue measuring 5.2 x 4.1

1.1 cm. Representative lymph nodes are identified. The largest measures 2.1 cm in greatest dimension,

[page 4 of 8]
and has a semi-firm, tan-white parenchyma. Representative nodes are submitted in cassettes

Part E, labeled "right obturator lymph node," consists of one piece of fibrofatty tissue and associated lymph

node, measuring 6.2 x 2.3 x 1.6 cm. On cut section, the largest, identifiable lymph node measures 0.5 cm

in greatest dimension, and is tan-white. Lymph nodes are submitted in cassettes

Page 3 of 8

Part F, labeled "left pelvic lymph node," consists of four fragments of fibrofatty tissue measuring 3.4 x 2.1 x

1.6 cm. Representative lymph node candidates measure 1.0 cm in greatest dimension, and have a

tan-yellow parenchyma. The nodes are submitted in cassettes

Part G, labeled "small bowel adhesions," consists of one piece of tan-red, semi-soft tissue measuring 2.1 x

0.7 x 0.4 cm. The specimen is entirely submitted in cassette

Part H, labeled "small bowel mesentery," consists of one piece of soft, tan-red tissue measuring 1.2 x 0.6 x

0.6 cm. The specimen is entirely submitted in cassette

Part I, labeled "small bowel mesentery #2," consists of one piece of semi-soft, tan-red tissue measuring 1.1 x

0.7 x 0.6 cm. The specimen is entirely submitted in cassette

Part J, labeled "sigmoid tumor," consists of multiple fragments of firm, tan tissue measuring 2.1 x 1.1 x 0.6

cm in aggregate. The specimen is entirely submitted in cassette

Part K, labeled "omentum #2," consists of two pieces of fibrofatty tissue measuring 3.1 x 1.2 x 0.7 cm in

aggregate. The specimens contain several small, white firm nodules, measuring 0.7 cm in greatest

dimension. Representative sections are submitted in cassette

Part L, labeled "infraglottic omentum," consists of one piece of fibrofatty tissue measuring 3.2 x 2.8 x 1.2

cm. On cut section, there is a firm, infiltrating white mass in the center of the specimen, measuring

approximately 2.4 cm in greatest dimension. Representative sections are submitted in cassette

Part M, labeled "ileum," consists of a segment of bowel and associated mesentery, measuring 30.1 cm in

length, with a diameter of 2.0 cm. On the serosal surface of the specimen, there are several areas of

adhesions, which are formed from infiltrating white plaques. These plaques do not appear to penetrate into

the muscularis propria of the ileum. Representative sections are submitted as follows:

Cassettes: Distal margins of ileum.

Cassette: Representative portion of center of ileum.

Cassettes: Serosal nodules.

Part N, labeled "hepatic flexure tumor," consists of one piece of fibrofatty tissue, measuring 2.1 x 1.0 x 0.8

cm. In the center of the specimen, there is a firm, white infiltrating nodule, measuring 1.0 cm in greatest

dimension. Representative sections are submitted in cassette N1.

Part O, labeled "cecum," consists of a portion of large bowel, measuring 6.0 x 4.2 x 3.2 cm. Cut section

reveals unremarkable, large intestinal mucosa. The serosal surface contains one area with a small, white

nodule, measuring 0.6 cm in greatest dimension. The nodule contains a white, firm

[page 5 of 8]
parenchyma. The
specimen is submitted as follows:
Cassettes Margins.
Cassettes Representative sections of nodule

Other Specimens

Specimen(s) Received: immunohistostaining & interpretation only

Final Diagnosis

Immunohistochemical stain and interpretation for HER-2/*neu*--

Peritoneum, segmental resection of ileum () This
metastatic serous

carcinoma is negative for overexpression of Her-2/*neu* oncoprotein; see
comment.

Specimen(s) Received: Ascitic Fluid

Final Diagnosis

Ascitic Fluid

ADENOCARCINOMA, METASTATIC.

See Below

Specimen Class **Status:** Signed Out

Specimen(s) Received: A: Small bowel adhesion, B: Abdominal wall adhesion, C: Small
bowel adhesion, D: Right lower quadrant
nodule, E: Colon adhesions, F: Ileum, G: Small bowel mesentary

Final Diagnosis

A. Small bowel, adhesion, biopsy:

Metastatic serous carcinoma; see comment.

[page 6 of 8]
2. Fibrin deposition.

3. Fibrosis with acute and chronic inflammation.

B. Peritoneum, abdominal wall adhesion, biopsy: Metastatic serous carcinoma.

C. Small bowel, adhesion, biopsy:

1. Metastatic serous carcinoma.

2. Fibrosis.

D. Abdomen, right lower quadrant nodule, biopsy: Calcific nodule with benign

mucinous epithelium; see comment.

E. Colon, adhesions, biopsy:

1. Metastatic serous carcinoma.

2. No evidence of carcinoma in one lymph node (0/1).

F. Ileum, segmental resection:

1. Metastatic serous carcinoma on serosal surface.

2. Fibrosis.

Page 5 of 8

G. Small intestine, mesentery, biopsy: Metastatic serous carcinoma.

Specimen(s) Received: Right Upper Quadrant wash

Final Diagnosis

Right Upper Quadrant Wash

ADENOCARCINOMA, METASTATIC.

Signed Out: 6/27/2008 12:12

Specimen(s) Received: A: Diaphragm adhesion, B: RT upper quadrant adhesion, C: Bowel adhesion, D: Gallbladder

Final Diagnosis

A. Diaphragm, biopsy: Microscopic focus of serous carcinoma; see comment.

B. Peritoneum, right upper quadrant, biopsy: No carcinoma identified.

C. "Bowel adhesion", biopsy: No carcinoma identified.

D. Gallbladder, cholecystectomy:

1) Chronic cholecystitis.

2) Cholelithiasis.

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

[page 7 of 8]
CELLULAR CHANGES WITHIN NORMAL LIMITS.

Atrophic pattern

SPECIMEN ADEQUACY:

Specimen(s) Received: A: Peritoneal Washing, B: Diaphragm, Right Hemidiaphragm, C: Diaphragm, Left Hemidiaphragm

Final Diagnosis

A: Peritoneal Washing

ADENOCARCINOMA.

B: Diaphragm, Right Hemidiaphragm

Page 6 of 8

BENIGN.

C: Diaphragm, Left Hemidiaphragm

BENIGN.

Specimen(s) Received: A: small bowel adhesion, fs, B: small bowel adhesion #2, fs, C: right lower quadrant, fs, D: Bladder, biopsy, peritoneum, E: Soft tissue, NOS, cul-de-sac, F: Soft tissue, NOS, cul-de-sac #2, G: Soft tissue, NOS, left pelvis, H: Soft tissue, NOS, left gutt

Final Diagnosis

A. Small bowel adhesion, biopsy: Skeletal muscle with no tumor identified.

B. Small bowel adhesion #2, biopsy: Foreign-body giant-cell reaction with foreign material, no tumor identified; see comment.

C. Right lower quadrant, biopsy: Fibrous tissue with no tumor identified; see comment.

D. Bladder, biopsy: Fibrofatty tissue, no tumor identified.

E. Cul-de-sac, biopsy: Fibrofatty tissue with focal calcification and foreign-body giant-cell reaction, no tumor identified.

F. Cul-de-sac #2, biopsy: Fibrofatty tissue, no tumor identified.

G. Left pelvis, biopsy: Fibrofatty tissue, no tumor identified.

H. Left gutter, biopsy: Fibrofatty tissue, no tumor identified.

I. Right lower quadrant adhesion, biopsy: Fibrofatty tissue, no tumor identified.

J. Right pelvic adhesion, biopsy: Intestinal wall tissue with no tumor identified.

K. Anterior abdominal wall, adhesion, biopsy: Fatty tissue, no tumor identified.

L. Right upper quadrant adhesion, biopsy: Fatty tissue, no tumor identified.

M. Peritoneum, biopsy: Fibroadipose tissue, no tumor identified.

N. Anterior abdominal wall scar, biopsy: Fibroadipose tissue and skeletal muscle, no

[page 8 of 8]
tumor identified.

O. Right gutter, biopsy: Fibroadipose tissue, no tumor identified.

P. Bladder, anterior portion, biopsy: Fibroadipose tissue, no tumor identified.

Page 7 of 8

Q. Cul-de-sac, biopsy: Fibrous tissue, no tumor identified.

R. Right pelvis, biopsy: Fibroadipose tissue and portion of mesothelium, no tumor

Specimen(s) Received: Peritoneal washing

Final Diagnosis

Peritoneal Washing

ADENOCARCINOMA.

See Below.

Specimen(s) Received: CERVICAL

Final Diagnosis

BENIGN

Source: NCI Genomic Data Commons file 54eb969e-46c2-4c1b-b7af-a26eb9da08cd (TCGA-09-1661.1910251F-8C5C-4067-91DC-87BFDAF77283.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).